Somatic mutation profile of tumor specimen TCGA-YL-A8S8-01A (aliquot TCGA-YL-A8S8-01A-11D-A377-08) from TCGA case TCGA-YL-A8S8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.8 years (25,119 days).
Specimen TCGA-YL-A8S8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33adcc25-b7fc-4ad6-98b3-a9dfc988acac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8S8-10A (Blood Derived Normal), aliquot TCGA-YL-A8S8-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/554f4ca0-18b8-4ccb-9ada-281a9ee3c13a

The open-access MAF lists 42 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.259T>A p.Y87N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1057519972, COSV61652887, COSV61655982; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.868A>G p.K290E | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100815337; called by muse, mutect2, varscan2
- APC | c.4199C>A p.S1400* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as CM995167, COSV57324455, COSV57326621, COSV57333132; called by muse, mutect2, varscan2
- BEST2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs371801091; called by muse, mutect2, varscan2
- BMT2 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1453581510, COSV99774924; called by muse, mutect2, varscan2
- CACNA1C | c.1260T>A p.D420E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.97); catalogued as COSV100223391; called by muse, mutect2
- CEP192 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100382366, COSV58070819; called by muse, mutect2, varscan2
- CHD5 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs141210110, COSV99314074; called by muse, mutect2, varscan2
- CHTF18 | c.1941G>T p.K647N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779438509, COSV99243851; called by muse, mutect2, varscan2
- DCLRE1C | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740016; called by muse, mutect2, varscan2
- DIP2A | c.4479G>A p.W1493* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100595588; called by muse, mutect2, varscan2
- EIF4H | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.939); catalogued as rs1210127883, COSV56081884; called by muse, mutect2, varscan2
- ELF1 | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.345); catalogued as COSV99523401; called by muse, varscan2
- FANCD2 | c.3390T>A p.C1130* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99812816; called by muse, mutect2, varscan2
- GALNT14 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs968735687, COSV100205821; called by muse, mutect2, varscan2
- IHO1 | c.1642T>C p.S548P | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as COSV99606689; called by muse, mutect2, varscan2
- MANEA | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468563017, COSV100721705; called by muse, mutect2, varscan2
- MID1 | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.599); catalogued as COSV100452800; called by muse, mutect2, varscan2
- MYT1L | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs781013816, COSV67723791; called by muse, mutect2, varscan2
- PHF1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1025779493, COSV100992702; called by muse, mutect2
- PKD1L2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs369884548; called by muse, mutect2, varscan2
- RAG1 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV100201229; called by muse, mutect2, varscan2
- RUSC1 | c.2372C>T p.P791L (on ENST00000368352 / NM_001105203.2; = p.P322L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99430405; called by muse, mutect2, varscan2
- SBF2 | c.3978+2T>C p.X1326_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99816123; called by muse, mutect2, varscan2
- SCNM1 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99766262; called by muse, mutect2, varscan2
- SLC27A5 | c.1100T>A p.F367Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99564685; called by muse, mutect2, varscan2
- SRCAP | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1485334969, COSV99351642; called by muse, mutect2, varscan2
- TGIF2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs920189969, COSV65836668; called by muse, mutect2, varscan2
- TNNI1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780250818, COSV60189249; called by muse, varscan2
- CCL15 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDC20 | c.649del p.L217Cfs*48 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- CT45A1 | c.166_167del p.K56Efs*18 | Frame Shift Del (DEL) | VAF 56/665 reads (8%) | called by mutect2, pindel
- FBXO38 | c.1684dup p.T562Nfs*14 | Frame Shift Ins (INS) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
- KIRREL1 | c.1204_1225del p.Y402Afs*16 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- NSL1 | c.175_176dup p.L60Sfs*61 | Frame Shift Ins (INS) | VAF 28/181 reads (15%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.2905_2911+16del p.X969_splice | Splice Site (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel
- AMIGO3 | c.867C>T p.Y289= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs371379790, COSV57539108; called by muse, mutect2, varscan2
- ARF1 | c.27C>T p.F9= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV99683395; called by muse, mutect2, varscan2
- CHST12 | c.930G>A p.P310= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs1454655848, COSV51678982, COSV99324603; called by muse, mutect2, varscan2
- LOXL3 | c.1329C>T p.G443= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs765730873, COSV99240026; called by muse, mutect2, varscan2
- MUC6 | c.1317C>T p.Y439= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs745628982, COSV70142876; called by muse, mutect2, varscan2
- ZNF536 | c.915C>T p.C305= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs551108092, COSV62823301; called by muse, mutect2, varscan2
